Gene-level copy-number profile of tumor specimen TCGA-DD-AADV-01A from TCGA case TCGA-DD-AADV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.1 years (18,300 days).
Specimen TCGA-DD-AADV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.09594e0c-6d9e-4e6f-b3f3-784ca29aacca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebc9f5b7-2398-4849-8dc6-dd2fecf3e1d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 19,048; copy number 2: 38,902; copy number 3: 1,785; copy number 4: 57; copy number 9: 8; copy number 17: 2; copy number 18: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADV-01A-11D-A38W-01): tumor purity 0.88, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:25,555,543–25,555,606, 1 gene: AC093416.1.
- chr13:51,584,455–51,767,709, 1 gene (within-gene range 0–1): WDFY2.
- chr13:51,763,951–51,866,232, 5 genes: AL162377.3, DHRS12, AL162377.1, TMEM272, CCDC70.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:29,287,011–29,921,653, 14 genes, copy number 9–18 (within-gene range 4–18): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58.

Autosomal genes at a single copy (total copy number 1): 16,666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
